FM case AD2356 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/de2fb998-0d1a-469f-973e-eb087af4f121

Female, 75.7 years: Carcinoma, NOS (ICD-O-3 8010/3) of the pancreas; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
